Gene-level copy-number profile of tumor specimen TCGA-DD-A1EL-01A from TCGA case TCGA-DD-A1EL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 23.5 years (8,573 days).
Specimen TCGA-DD-A1EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9d66847c-dcc1-46b6-a1f5-7ab7fcb1a1e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A1EL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7725c047-b596-4fc9-8839-00204902f697

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 12,041; copy number 3: 8,771; copy number 4: 31,110; copy number 5: 1,888; copy number 6: 3,114; copy number 7: 2,552; copy number 8: 302; copy number 9: 13; copy number 10: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A1EL-01A-11D-A151-01): tumor purity 0.82, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,579,089–150,721,478, 3 genes: AC110813.1, MAB21L2, ZBTB8OSP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 37 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:191,678,068–191,741,097, 1 gene, copy number 10 (within-gene range 5–10): NABP1.
- chr2:191,733,428–192,194,933, 6 genes, copy number 10: NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2.
- chr2:193,730,555–195,026,370, 13 genes, copy number 9: SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1.
- chr2:196,967,017–197,311,173, 1 gene, copy number 10 (within-gene range 5–10): ANKRD44.
- chr2:197,197,991–197,676,045, 16 genes, copy number 10: ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
